Surgical pathology report (de-identified scan), TCGA case TCGA-09-2053, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-2053-01C (Primary Tumor).

[page 1 of 6]
FINAL PATHOLOGIC DIAGNOSIS

- A. Left ovary, salpingo-oophorectomy: Ovarian serous carcinoma with direct extension to fallopian tube; see comment.
- B. Uterus, right adnexa, hysterectomy and salpingo -oophorectomy:
- Serosa: No significant pathologic abnormality.
- Myometrium: No significant pathologic abnormality.
- Endometrium: Atrophy.
- Cervix: No significant pathologic abnormality.
- Right ovary: Surface adhesions and epithelial inclusions.
- Right Fallopian tube: Paratubal cysts.
- Separate fragment of serous carcinoma; see comment.
- C. Diaphragm, biopsy: Serous carcinoma.
- D. Periureteral soft tissue, biopsy: Serous carcinoma.
- E. Recto-sigmoid colon, segmental resection:
1. Serous carcinoma involving serosa with direct invasion of muscularis.
2. Metastatic carcinoma in two lymph nodes (2/9).
- F. Omentum, omentectomy: Serous carcinoma.
- G. Diaphragm, biopsy: Serous carcinoma.
- H. Right periaortic lymph nodes, dissection: No tumor (0/9).
- I. Left periaortic lymph nodes, dissection: No tumor (0/12).
- J. Right pelvic lymph nodes, dissection: No tumor (0/12).
- K. Left pelvic lymph nodes, dissection: No tumor (0/12).
- L. Mesentery, biopsy: Serous carcinoma.
- M. Colon, resection margins, excision: No tumor.
- N. Abdominal wall, biopsy:
- Cauterized atypical cells, suspicious for serous carcinoma.

COMMENT:

Ovarian Tumor Synoptic Comment

1. Type of tumor: Serous carcinoma.
2. Grade of tumor: High grade.
3. Location of tumor: Left ovary.
4. Diameter of tumor: 7.0cm.
5. Appearance of surface of ovary: Smooth.
6. Condition of capsule: Intact.
7. Appearance of cut surface: Solid and cystic, mainly cystic.
8. Color of solid areas: Tan-yellow.
9. Necrosis: Focally present.
10. Lymphatic/vascular invasion: Not identified.
11. Sites of metastases in pelvis: Ipsilateral fallopian tube lumen; serosal involvement of recto-sigmoid

[page 2 of 6]
colon.

12. Pelvic lymph nodes: Metastatic carcinoma present in two lymph nodes (2/33).

13. Sites of metastases in abdomen: Omentum, diaphragm, mesentery.

14. Para-aortic lymph nodes: No carcinoma identified in twenty-one lymph nodes (0/21).

15. Peritoneal cytology: Benign. Cytology accession number: [REDACTED]

16. Other significant findings: None.

17. FIGO stage: IIIC.

18. TNM stage: pT3cN1MX.

In the hysterectomy specimen (Part B), a separate tissue fragment was present in the specimen container.

Microscopic evaluation demonstrated serous carcinoma. This fragment likely represents a detached fragment of the left ovary.

Specimen(s) Received

A: Left ovary (FS)

B: Uterus, right ovary and cervix

C: Diaphragm nodule (FS)

D: Ureteral implant

E: Rectus sigmoid colon

F: Omentum

G: Diaphragm nodule

H: Right periaortic lymph node

I: Left periaortic lymph node

J: Right pelvic lymph node

K: Left pelvic lymph node

L: Mesenteric lymph node

M: Donut

Page 2 of 6

N: Abdominal wall nodule

Intraoperative Diagnosis

FS1 (A) Left ovary and tube, salpingo-oophorectomy: Poorly differentiated carcinoma. [REDACTED]

FS2 (C) Diaphragm nodule, biopsy: Poorly differentiated carcinoma. (Dr. [REDACTED]).

Clinical History

The patient is a [REDACTED] with a complex left adnexal mass suspicious for ovarian carcinoma.

[REDACTED] undergoes exploratory laparotomy, total abdominal hysterectomy- bilateral salpingo-oophorectomy, partial colectomy, lymph node dissection and staging biopsies.

Gross Description

The specimen is received from the Operating Room in 14 parts, each labeled with the patient's name and medical record number. Parts A through C are received fresh, and Parts D through N are received in formalin.

Part A is additionally labeled "left ovary - [REDACTED]," and consists of a left ovary and

[page 3 of 6]
[REDACTED]

Fallopian tube. The ovary weighs 36 grams and measures 7.0 x 4.5 x 2.5 cm. The serosal surface is smooth and gray-white with an intact capsule. Sectioning reveals a unilocular cyst measuring 7.0 x 4.3 x 2.4 cm that contains serosanguinous fluid. The cyst wall demonstrates multiple tan-yellow solid areas that vary from plaque-like to complex exophytic friable masses that fill approximately 40% of the cyst volume. No normal ovarian parenchyma is grossly identified. The fallopian tube measures 5 cm in length and 1.0 cm in average diameter. Its serosal surface is tan-red and smooth. On sectioning, the lumen is filled and mildly distended by grossly adherent friable tan-yellow material. A portion of the cyst wall is sent to [REDACTED]

further studies. An additional section of the cyst wall is frozen for intraoperative consultation and the remnant is submitted in cassette A1. Gross photographs are taken and additional representative sections are submitted as follows:

Cassette A1: Frozen section remnant.

Cassettes A2-A3: Ovary.

Cassette A4: Ovary and Fallopian tube.

Cassette A5: Fallopian tube.

Cassette A6: Ovary.

Part B is additionally labeled "uterus, right ovary and cervix - fresh," and consists of a uterus with attached cervix and left adnexa weighing 70 grams. The uterus measures 9 cm from fundus to cervix, 3.5 cm from cornu to cornu and 2.7 cm from anterior to posterior, and is oriented by the relationship of the round ligament to the fallopian tubes and the peritoneal reflections. The serosa is smooth and unremarkable.

The uterine cavity sounds to 6.2 cm. The transition zone and endocervical canal are unremarkable. The endometrium is tan, measures 0.1cm, and contains no polyps. The myometrium measures 1.2 cm in thickness; no leiomyomata are present. The right fallopian tube measures 7.1 cm in length and 0.6 cm in average diameter. The serosal surface is smooth and tan-gray. The fimbria are lush. On cut section,

multiple paratubal cysts are identified. The tubal lumen is patent and grossly unremarkable. The left right measures 2.8 x 1.0 x 0.6 cm. The surface is smooth. The cut surface is unremarkable. Representative sections are submitted as follows:

Cassette B1: Anterior cervix.

Cassette B2: Posterior cervix.

Cassette B3: Anterior endomyometrium.

Cassette B4: Posterior endomyometrium

Cassette B5: Right ovary.

Cassette B6: Distal fallopian tube including paratubal cyst.

Cassette B7: Fallopian tube and ligaments adjacent to uterus.

[page 4 of 6]
Cassettes B8-B9: Posterior cul de sac fat.

Also present in the specimen container is a single separate unoriented fragment of yellow-tan friable soft

Page 3 of 6

tissue measuring 2.5 x 1.4 x 0.7cm. It is bisected and entirely submitted in cassette B10.

Part C is additionally labeled "diaphragm nodule frozen section," consists of a single firm, irregular,

unoriented piece of pink-tan tissue measuring 0.6 x 0.5 x 0.1 cm. The entire specimen is frozen for frozen

section 3, with the remnant submitted in cassette C1.

Part D is additionally labeled "ureteral implant." It consists of multiple irregular and extensively fragmented

pieces of soft, pink-brown tissue, measuring 2.4 x 2.0 x 0.4 cm in aggregate. The specimen is entirely

submitted in cassettes D1 and D2.

Part E is additionally labeled "rectosigmoid." It consists of an unoriented segment of large bowel,

measuring 27.1 cm in length and 3.7 cm in average diameter. One margin of the specimen has been

stapled shut (inked blue), and the other end is open (inked black). The attached omentum demonstrates a

friable, fungating, gray-brown mass, measuring 10.8 x 4.7 x 3.6 cm; this extends to within 6.5 cm of the

black-inked margin and appears to have been grossly transected at the radial margin. In addition, two

additional masses are identified on the antimesenteric serosal surface of the colon; the first of these

measures 1.8 x 1.5 x 1.5 cm and is present 1.8 cm from the black-inked margin, and the second of these

measures 1.2 x 0.8 x 0.5 cm and is present 8.6 cm from the blue-inked surgical margin. The colonic

mucosa is gray-tan and contains the normal mucosal folds. No mucosal masses or nodules are grossly

apparent. The previously identified serosal nodules do not appear to erode through to the mucosal surface.

The radial surgical margin is inked black. Representative sections are submitted as follows:

Cassette E1: Lateral margin.

Cassettes E2-E4: Mesenteric mass.

Cassette E5: Serosal mass #1.

Cassette E6: Serosal mass #2.

Cassettes E7-E8: Candidate lymph nodes, entirely submitted.

Part F is additionally labeled "omentum." It consists of a single roughly rectangular piece of firm,

yellow-tan fatty tissue, measuring 44.0 x 9.0 x 2.5 cm and weighing 285 gm.

Multiple firm, irregular

nodules are found scattered and embedded throughout the specimen; they range in size from 0.5 cm to 4.0

cm in greatest dimension. Representative sections of various lesions and omentum are submitted in

cassettes F1 through F5.

[page 5 of 6]
Part G is additionally labeled "diaphragm nodule." It consists of a single irregular piece of firm, yellow-tan tissue, measuring 2.2 x 1.7 x 1.5 cm. On one surface is a round nodule, measuring 1.0 x 0.9 x 0.6 cm.

The specimen is serially sectioned and entirely submitted in cassettes G1 and G2. Part H is additionally labeled "right periaortic lymph node." It consists of a single irregular piece of soft, yellow-brown fatty tissue, measuring 5.0 x 3.2 x 1.5 cm. The specimen is examined for candidate lymph nodes, and multiple candidate lymph nodes are found, ranging from 0.5 cm to 1.2 cm in greatest

dimension. Candidate lymph nodes are submitted as follows:

Cassette H1: One node, bisected.

Cassette H2: One node, bisected.

Cassette H3: Two whole nodes.

Cassette H4: Two nodes, each bisected.

Cassette H5: One node, bisected.

Cassette H6: Three whole nodes.

The remaining tissue is returned to the container.

Part I is additionally labeled "left periaortic lymph node." It consists of a single irregular piece of soft, yellow-brown fatty tissue, measuring 6.5 x 3.4 x 2.2 cm. The specimen is examined for candidate lymph nodes, and multiple candidate nodes are found, ranging from 0.3 cm to 1.9 cm in greatest dimension.

Candidate lymph nodes are submitted as follows:

Cassette I1: Multiple whole nodes.

Cassettes I2-I3: One node, trisected.

Cassettes I4-I5: One node, trisected.

Page 4 of 6

Cassette I6: One node, bisected.

Cassette I7: One node, bisected.

Cassette I8: Two nodes, each bisected.

Cassette I9: Two nodes, each bisected.

Cassette I10: Two nodes, one bisected.

The remaining tissue is returned to the container.

Part J is additionally labeled "right pelvic lymph node." It consists of multiple irregular pieces of soft, yellow-brown fatty tissue, measuring 8.0 x 5.0 x 2.0 cm in aggregate. The specimen is examined for

candidate lymph nodes, and multiple candidate nodes are found, ranging from 0.2 cm to 2.2 cm in greatest

dimension. Candidate lymph nodes are submitted as follows:

Cassette J1: Multiple whole nodes.

Cassettes J2-J3: One node, serially sectioned.

Cassette J4: Two nodes, each bisected.

Cassette J5: Two nodes, each bisected.

Cassettes J6-J7: One node, trisected.

Cassette J8: One node, bisected.

Cassette J9: One node, bisected.

Cassette J10: Two whole nodes.

Cassettes J11-J12: One node, serially sectioned.

[page 6 of 6]
[REDACTED]

The remaining tissue is returned to the container.

Part K is additionally labeled "left pelvic lymph node." It consists of multiple irregular pieces of soft,

yellow-brown fatty tissue, measuring 6.4 x 5.3 x 2.0 cm in aggregate. The specimen is examined for

candidate lymph nodes, and multiple candidate nodes are found, ranging from 0.3 cm to 2.7 cm in greatest

dimension. Candidate lymph nodes are submitted as follows:

Cassette K1: One node, bisected.

Cassette K2: Multiple whole nodes.

Cassette K3: Two whole nodes.

Cassette K4: One node, bisected.

Cassette K5: One node, bisected.

Cassette K6: One node, bisected.

Cassette K7: One node, bisected.

Cassette K8: Two whole nodes.

Part L is additionally labeled "mesenteric lymph node." It consists of a single ovoid piece of firm, white-tan

tissue, measuring 1.5 x 1.1 x 0.8 cm. The specimen is trisected and entirely submitted in cassette L1.

Part M is additionally labeled "donuts." It consists of a single hard, roughly umbrella-shaped, silver-gray,

synthetic bowel ring rod, measuring 7.3 x 2.8 x 2.0 cm. Sutured onto the rod are two ring-shaped pieces of

soft, pink-tan intestinal tissue, measuring 2.0 x 1.6 x 0.7 cm and 1.9 x 1.5 x 1.0 cm.

The intestinal rings

are unoriented. Each has a smooth, tan mucosa. Each bowel ring is removed from

the rod. The margin of

the smaller ring is inked blue, and the margin of the larger ring is inked green. Each ring is radially

sectioned, and no lesions are found. A blue suture runs through each ring.

Representative radial sections

of the smaller bowel ring are submitted in cassette M1. Representative radial

sections of the larger bowel

ring are submitted in cassette M2.

Part N is additionally labeled "abdominal wall nodule." It consists of a single irregular piece of firm,

red-tan/white tissue, measuring 1.2 x 0.8 x 0.6 cm. The specimen is bisected and entirely submitted in

cassette N1.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending

pathologist following review of all pathology slides.

[REDACTED]

Source: NCI Genomic Data Commons file 125132c7-9ae8-4e9b-8c49-ef2f25bd3dbe (TCGA-09-2053.0D28E549-3ED0-4A22-BAC7-9CBE24E44F53.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).